Somatic mutation profile of cancer-model specimen HCM-BROD-0001-C18-85M (3D Air-Liquid Interface Organoid, passage 24; aliquot HCM-BROD-0001-C18-85M-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-BROD-0001-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: GX; Age at diagnosis: 47.4 years (17,316 days).
Specimen HCM-BROD-0001-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Air-Liquid Interface Organoid; Preservation method: Frozen; Passage count: 24.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71876fad-df47-4b41-a083-9bd5fd1406a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0001-C18-10A (Blood Derived Normal), aliquot HCM-BROD-0001-C18-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d80e6569-4c72-46f9-a692-2e369b6cb97c

The open-access MAF lists 499 somatic variants for this specimen: 177 protein-altering or splice-affecting, 293 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 293, Missense Mutation 150, Intron 21, Nonsense Mutation 9, Frame Shift Del 6, Splice Region 4, 5'UTR 3, 5'Flank 2, In Frame Ins 2, Frame Shift Ins 2, In Frame Del 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 158/160 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 261/261 reads (100%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 137/258 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58055203; called by muse, mutect2, varscan2
- ADGRL3 | c.1597C>T p.R533W (on ENST00000506720 / NM_001322402.2; = p.R465W on NM_015236.6) | Missense Mutation (SNP) | VAF 115/249 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs761335675; called by muse, mutect2, varscan2
- ANGPT4 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 136/395 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs746445808, COSV67921665; called by muse, mutect2, varscan2
- ANKRD17 | c.2354G>A p.S785N | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.439); catalogued as COSV58215246; called by muse, varscan2
- ANKS1B | c.2924C>T p.P975L | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.915); catalogued as COSV59125281; called by muse, varscan2
- APBA1 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 242/556 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV99597338; called by muse, varscan2
- ATXN7L1 | c.1546C>A p.L516M | Missense Mutation (SNP) | VAF 46/808 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV66300957; called by muse, mutect2
- BCL9 | c.155A>C p.Q52P | Missense Mutation (SNP) | VAF 126/934 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV52340378; called by muse, varscan2
- BEGAIN | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 494/778 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1297371425, COSV62068140; called by muse, mutect2, varscan2
- BMP10 | c.434T>G p.L145R | Missense Mutation (SNP) | VAF 233/498 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770302; called by muse, mutect2, varscan2
- BRD4 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 268/288 reads (93%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs201971332; called by muse, mutect2, varscan2
- C1orf94 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV64913180; called by muse, varscan2
- C2CD3 | c.2437G>C p.D813H | Missense Mutation (SNP) | VAF 231/350 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV58102114; called by muse, mutect2, varscan2
- CACNA1C | c.4624C>T p.R1542C | Missense Mutation (SNP) | VAF 230/431 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59697521; called by muse, mutect2, varscan2
- CACNA1G | c.6026T>C p.M2009T | Missense Mutation (SNP) | VAF 64/406 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs866426899; called by muse, mutect2
- CCAR1 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as COSV56266822; called by muse, mutect2, varscan2
- CDH18 | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 82/337 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56913399, COSV56917707; called by muse, mutect2
- CLDN25 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 276/448 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746964341, COSV101493608; called by muse, mutect2, varscan2
- COL7A1 | c.6892C>T p.P2298S | Missense Mutation (SNP) | VAF 128/429 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60403546; called by muse, mutect2, varscan2
- CSMD1 | c.1717C>A p.Q573K (on ENST00000520002; = p.Q572K on NM_033225.6) | Missense Mutation (SNP) | VAF 211/211 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV100144606; called by muse, mutect2, varscan2
- CSMD3 | c.4337A>C p.E1446A (on ENST00000297405 / NM_001363185.1; = p.E1342A on NM_052900.3) | Missense Mutation (SNP) | VAF 45/333 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs1487728451, COSV99831023; called by muse, mutect2, varscan2
- CYP26A1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 239/631 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs200654050; called by muse, mutect2, varscan2
- DHRS4L2 | c.553A>T p.S185C | Missense Mutation (SNP) | VAF 121/302 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs1266693873; called by muse, mutect2, varscan2
- DUSP19 | c.429T>C p.D143= | Splice Region (SNP) | VAF 54/270 reads (20%) | catalogued as rs765039924; called by muse, mutect2, varscan2
- EBF3 | c.1499G>A p.S500N (on ENST00000355311 / NM_001375392.1; = p.S491N on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/450 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62471376, COSV62475439; called by muse, mutect2, varscan2
- EPHA3 | c.2917G>T p.E973* | Nonsense Mutation (SNP) | VAF 136/409 reads (33%) | catalogued as COSV100341511; called by muse, mutect2, varscan2
- EYA3 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 35/338 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as rs1341798011; called by muse, varscan2
- FAM47C | c.1424G>T p.C475F | Missense Mutation (SNP) | VAF 180/182 reads (99%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.491); catalogued as COSV63723820; called by muse, mutect2, varscan2
- FIGNL2 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 544/880 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.347); catalogued as rs1408652556; called by muse, varscan2
- FNBP1L | c.1063T>C p.F355L | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.302); catalogued as COSV53091197; called by muse, varscan2
- GHR | c.1169G>A p.C390Y | Missense Mutation (SNP) | VAF 109/221 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs949031881, COSV50119144; called by muse, mutect2, varscan2
- GXYLT2 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 105/422 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs1281977380; called by muse, mutect2, varscan2
- HEPHL1 | c.3280C>T p.R1094* | Nonsense Mutation (SNP) | VAF 98/284 reads (35%) | catalogued as rs546075822; called by muse, mutect2, varscan2
- HNRNPC | c.325A>C p.T109P | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV60143681; called by muse, mutect2, varscan2
- HTR2A | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 143/275 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs376305063; called by muse, mutect2, varscan2
- IQCF5 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 199/623 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs1190575303, COSV71306819; called by muse, mutect2, varscan2
- IVNS1ABP | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 96/404 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV62250111; called by muse, mutect2
- JAG2 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 113/1440 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1285754373, COSV59306364; called by muse, mutect2
- KALRN | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 137/396 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs758760625, COSV53761733; called by muse, mutect2, varscan2
- KIAA1841 | c.952C>G p.R318G | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.648); catalogued as rs199876206, COSV54374561; called by muse, mutect2, varscan2
- KTN1 | c.3947C>T p.T1316M (on ENST00000395314 / NM_001271014.2; = p.T1259M on NM_004986.4) | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs548275870; called by muse, mutect2, varscan2
- LAMC3 | c.3520G>A p.A1174T | Missense Mutation (SNP) | VAF 136/320 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1355839170; called by muse, mutect2, varscan2
- LRP1B | c.3672C>A p.C1224* | Nonsense Mutation (SNP) | VAF 114/240 reads (48%) | catalogued as COSV67280723; called by muse, mutect2, varscan2
- LRRC6 | c.845dup p.K283Efs*12 | Frame Shift Ins (INS) | VAF 76/312 reads (24%) | catalogued as rs1391729028; called by mutect2, varscan2
- MAB21L4 | c.1154C>T p.P385L (on ENST00000388934 / NM_001085437.3; = p.P217L on NM_024861.4) | Missense Mutation (SNP) | VAF 252/492 reads (51%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.47); catalogued as rs745897108, COSV56744358; called by muse, mutect2, varscan2
- MARCHF3 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 110/271 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1036345702; called by muse, mutect2, varscan2
- MBD5 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 68/490 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV68695519; called by muse, mutect2
- MBP | c.538G>A p.G180S (on ENST00000355994 / NM_001025101.2; = p.G47S on NM_002385.3) | Missense Mutation (SNP) | VAF 38/383 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.012); catalogued as rs769290902, COSV62830761; called by muse, mutect2, varscan2
- MED13 | c.580A>G p.I194V | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1219819407; called by muse, mutect2
- MEF2A | c.261T>G p.T87= | Splice Region (SNP) | VAF 24/277 reads (9%) | catalogued as COSV57529786; called by muse, mutect2
- NCKAP1L | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs1165841354, COSV53207087; called by muse, mutect2, varscan2
- NECTIN1 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 244/832 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs750423713; called by muse, varscan2
- NIBAN2 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 311/312 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1046063862, COSV100030967; called by muse, mutect2, varscan2
- NR1D1 | c.1739T>C p.L580S | Missense Mutation (SNP) | VAF 108/500 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52840542; called by muse, varscan2
- NRG3 | c.1065A>C p.E355D | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV64552178; called by muse, mutect2
- NUMA1 | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 431/663 reads (65%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1314480088; called by muse, mutect2, varscan2
- OR6K3 | c.726G>T p.R242S (on ENST00000368146; = p.R226S on NM_001005327.2) | Missense Mutation (SNP) | VAF 89/340 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV63745416; called by muse, mutect2, varscan2
- OTOG | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 268/561 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs753472595; called by muse, mutect2, varscan2
- OTUD7A | c.1498G>A p.G500S (on ENST00000307050 / NM_001382637.1; = p.G493S on NM_130901.3) | Missense Mutation (SNP) | VAF 448/827 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as rs765651339, COSV61035747; called by muse, varscan2
- PARP4 | c.3994C>T p.R1332C | Missense Mutation (SNP) | VAF 159/323 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs200648886; called by muse, mutect2, varscan2
- PHF12 | c.2396A>G p.Y799C | Missense Mutation (SNP) | VAF 40/498 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs1398517820; called by muse, mutect2
- PHF20L1 | c.974A>T p.D325V | Missense Mutation (SNP) | VAF 76/616 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV55188488; called by muse, mutect2
- PHF3 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50312920; called by muse, mutect2, varscan2
- PRDM5 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs750031024, COSV53368548; called by muse, mutect2, varscan2
- PTBP3 | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52955923; called by muse, mutect2
- PYROXD1 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs752999723; called by muse, mutect2, varscan2
- RECQL4 | c.3167A>G p.Y1056C | Missense Mutation (SNP) | VAF 221/926 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs773143092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REV3L | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs748014293, COSV62621135; called by muse, mutect2, varscan2
- RHPN1 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 172/680 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs761122027; called by muse, mutect2, varscan2
- SAMSN1 | c.893G>T p.R298L (on ENST00000647101; = p.R70L on NM_001256370.1) | Missense Mutation (SNP) | VAF 200/301 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs546183526; called by muse, mutect2, varscan2
- SETD1B | c.20_22del p.P7del | In Frame Del (DEL) | VAF 53/367 reads (14%) | catalogued as rs777278685; called by mutect2, pindel, varscan2
- SLITRK2 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 559/767 reads (73%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs782605442, COSV59425870; called by muse, mutect2, varscan2
- SMAD4 | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 328/328 reads (100%) | catalogued as rs1568211615, CD040591, COSV61684525, COSV61684934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX16 | c.14A>G p.Y5C | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs368813947; called by muse, mutect2, varscan2
- SPRR2G | c.200del p.K67Sfs*50 | Frame Shift Del (DEL) | VAF 124/501 reads (25%) | catalogued as COSV100907401, COSV64202967, COSV64203011; called by mutect2, pindel, varscan2
- STN1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 79/496 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as rs761593090; called by muse, mutect2, varscan2
- TAF4 | c.148G>C p.V50L | Missense Mutation (SNP) | VAF 170/1501 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV53338809; called by muse, mutect2
- TLK1 | c.53A>G p.Q18R | Missense Mutation (SNP) | VAF 158/1084 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1435330040, COSV62629465; called by muse, mutect2
- TMEM198 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 416/654 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1190999055; called by muse, varscan2
- TTC3 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV61285660; called by muse, varscan2
- WDR20 | c.83C>A p.P28Q | Missense Mutation (SNP) | VAF 70/694 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV54470232; called by muse, mutect2, varscan2
- WNT9A | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 72/387 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1446374248; called by muse, mutect2
- ZEB2 | c.3643T>G p.*1215Eext*1 | Nonstop Mutation (SNP) | VAF 30/314 reads (10%) | catalogued as COSV57950967; called by muse, mutect2
- ZFAND4 | c.1393A>C p.S465R | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV60857842; called by muse, mutect2, varscan2
- ZNF326 | c.302G>C p.S101T | Missense Mutation (SNP) | VAF 74/394 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV61034132; called by muse, varscan2
- ZNF800 | c.1933T>A p.S645T | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.019); catalogued as COSV56173230; called by muse, varscan2
- ADAMTS12 | c.3607G>T p.D1203Y | Missense Mutation (SNP) | VAF 159/316 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS20 | c.2253G>C p.Q751H | Missense Mutation (SNP) | VAF 78/314 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ADAMTSL1 | c.4706G>T p.R1569M | Missense Mutation (SNP) | VAF 147/326 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB2 | c.2546del p.P849Lfs*69 | Frame Shift Del (DEL) | VAF 162/484 reads (33%) | called by mutect2, pindel, varscan2
- AIDA | c.46T>C p.F16L | Missense Mutation (SNP) | VAF 60/360 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- ANTXRL | c.812T>G p.V271G | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ASB4 | c.920G>A p.C307Y | Missense Mutation (SNP) | VAF 330/676 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, varscan2
- ATM | c.1970_1971del p.F657* | Frame Shift Del (DEL) | VAF 46/162 reads (28%) | called by mutect2, pindel, varscan2
- CACNA1G | c.6027G>T p.M2009I | Missense Mutation (SNP) | VAF 64/402 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- CCDC88C | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 228/884 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CD36 | c.493T>A p.S165T | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- CDC42BPB | c.792G>A p.W264* | Nonsense Mutation (SNP) | VAF 357/546 reads (65%) | called by muse, mutect2, varscan2
- CELF4 | c.1270T>C p.F424L | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2
- CFAP74 | c.1764A>G p.I588M | Missense Mutation (SNP) | VAF 82/227 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, varscan2
- CLIP1 | c.1430T>C p.I477T (on ENST00000620786 / NM_001247997.1; = p.I466T on NM_002956.2) | Missense Mutation (SNP) | VAF 52/332 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2
- CNOT4 | c.1634G>A p.S545N (on ENST00000541284 / NM_001190850.1; = p.S542N on NM_001190849.2) | Missense Mutation (SNP) | VAF 60/330 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, varscan2
- COL16A1 | c.2878G>T p.V960F | Missense Mutation (SNP) | VAF 102/344 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- COL21A1 | c.173A>T p.K58M | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CPM | c.383A>T p.D128V | Missense Mutation (SNP) | VAF 138/269 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DACH2 | c.134G>C p.S45T | Missense Mutation (SNP) | VAF 102/369 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- E2F8 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 396/778 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EIF6 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 103/402 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM71B | c.188T>A p.V63E | Missense Mutation (SNP) | VAF 67/301 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBXO15 | c.1492A>C p.S498R | Missense Mutation (SNP) | VAF 100/205 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FDPS | c.771G>C p.K257N | Missense Mutation (SNP) | VAF 102/341 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FHL1 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 45/369 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, varscan2
- FMO2 | c.55A>T p.K19* | Nonsense Mutation (SNP) | VAF 118/345 reads (34%) | called by muse, mutect2, varscan2
- GATA6 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 184/2036 reads (9%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.887); called by muse, mutect2
- GBP7 | c.969C>G p.N323K | Missense Mutation (SNP) | VAF 131/354 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GFRA4 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 261/927 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- GNAO1 | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 179/333 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- HERC2 | c.12544A>T p.S4182C | Missense Mutation (SNP) | VAF 28/696 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- HNRNPA1 | c.879_881dup p.G297dup | In Frame Ins (INS) | VAF 56/338 reads (17%) | called by mutect2, pindel, varscan2
- HNRNPUL1 | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 90/642 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- HS2ST1 | c.1050G>C p.K350N | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JPH2 | c.707G>C p.R236P | Missense Mutation (SNP) | VAF 252/1358 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- KCNV1 | c.1399A>T p.N467Y | Missense Mutation (SNP) | VAF 97/806 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KIF4A | c.2648A>C p.K883T | Missense Mutation (SNP) | VAF 118/240 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- KLHL22 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 87/206 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MARCOL | c.392G>T p.R131I | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MEDAG | c.731A>T p.E244V | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MSANTD2 | c.735T>G p.D245E (on ENST00000374979 / NM_001308027.2; = p.D193E on NM_024631.4) | Missense Mutation (SNP) | VAF 39/415 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MTDH | c.1050G>A p.G350= | Splice Region (SNP) | VAF 29/287 reads (10%) | called by muse, mutect2
- MTMR3 | c.3268T>G p.L1090V | Missense Mutation (SNP) | VAF 54/424 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- MYNN | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 100/209 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYO3A | c.3381A>C p.K1127N | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- NDST4 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- OCA2 | c.1705A>T p.T569S | Missense Mutation (SNP) | VAF 137/797 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- OR5L2 | c.631A>T p.I211F | Missense Mutation (SNP) | VAF 111/334 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- OTOF | c.3927_3928insCAG p.K1309_K1310insQ (on ENST00000272371 / NM_194248.3; = p.K542_K543insQ on NM_004802.4) | In Frame Ins (INS) | VAF 96/269 reads (36%) | called by pindel, varscan2
- PCDHA5 | c.1642G>A p.V548M | Missense Mutation (SNP) | VAF 302/615 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- PCDHGA6 | c.1400G>A p.R467K | Missense Mutation (SNP) | VAF 168/364 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PHF12 | c.1364A>C p.H455P | Missense Mutation (SNP) | VAF 52/582 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- PIWIL2 | c.2564A>G p.K855R | Missense Mutation (SNP) | VAF 181/181 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLEC | c.3530T>C p.V1177A (on ENST00000322810 / NM_201380.4; = p.V1067A on NM_000445.5) | Missense Mutation (SNP) | VAF 188/805 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- POLG | c.554T>A p.V185E | Missense Mutation (SNP) | VAF 58/823 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PPFIA2 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PPP1CC | c.730A>C p.I244L | Missense Mutation (SNP) | VAF 60/549 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.212); called by muse, varscan2
- PRRC2B | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PSD4 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 193/570 reads (34%) | called by muse, mutect2, varscan2
- RANBP2 | c.5433_5434del p.H1811Qfs*20 | Frame Shift Del (DEL) | VAF 88/302 reads (29%) | called by mutect2, pindel, varscan2
- RBBP5 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 44/351 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2
- RBM11 | c.166T>A p.C56S | Missense Mutation (SNP) | VAF 95/307 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- RETREG3 | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGMA | c.90C>G p.F30L | Missense Mutation (SNP) | VAF 52/569 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2
- ROCK1 | c.3758T>G p.F1253C | Missense Mutation (SNP) | VAF 100/221 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SACS | c.7426G>T p.V2476L | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- SAMSN1 | c.269C>G p.S90C | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- SCOC | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 180/364 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPINA11 | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 186/432 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SF3A3 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- SH2D4B | c.283A>C p.I95L | Missense Mutation (SNP) | VAF 139/386 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SLC44A1 | c.25_27del p.S9del | In Frame Del (DEL) | VAF 70/527 reads (13%) | called by pindel, varscan2
- SMC1B | c.1249G>T p.V417F | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, varscan2
- SPAG1 | c.1133A>T p.Q378L | Missense Mutation (SNP) | VAF 162/692 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, varscan2
- STK26 | c.1026A>C p.A342= | Splice Region (SNP) | VAF 74/237 reads (31%) | called by muse, mutect2, varscan2
- SUMF2 | c.818A>C p.K273T (on ENST00000652303; = p.*302Yext*5 on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/637 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- TCF12 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- TERF1 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 167/578 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TFAP2E | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 179/460 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TNS1 | c.3412C>T p.P1138S | Missense Mutation (SNP) | VAF 209/800 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TPTE | c.637dup p.R213Kfs*4 (on ENST00000618007 / NM_199261.4; = p.R195Kfs*4 on NM_199259.4) | Frame Shift Ins (INS) | VAF 10/43 reads (23%) | called by pindel, varscan2
- TRIOBP | c.5128del p.E1710Sfs*11 | Frame Shift Del (DEL) | VAF 92/221 reads (42%) | called by mutect2, pindel, varscan2
- TSHR | c.1736_1738delinsA p.A579Dfs*78 | Frame Shift Del (DEL) | VAF 215/605 reads (36%) | called by pindel, varscan2*
- VANGL2 | c.803T>C p.I268T | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- VAX1 | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 128/286 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VSIG1 | c.412+1_412+7del p.X138_splice | Splice Site (DEL) | VAF 160/290 reads (55%) | called by mutect2, pindel, varscan2
- ZNF618 | c.790C>T p.Q264* (on ENST00000374126 / NM_001318042.2; = p.Q252* on NM_133374.2) | Nonsense Mutation (SNP) | VAF 225/226 reads (100%) | called by muse, mutect2, varscan2
- ZNF804B | c.2358A>C p.K786N | Missense Mutation (SNP) | VAF 184/393 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABI2 | c.597C>A p.R199= (on ENST00000295851 / NM_001375719.1; = p.R193= on NM_005759.7 and 35 other RefSeq transcripts) | Silent (SNP) | VAF 82/570 reads (14%) | called by muse, mutect2
- AC068580.4 | c.969C>T p.G323= | Silent (SNP) | VAF 105/353 reads (30%) | catalogued as rs774332555, COSV99362376; called by muse, mutect2, varscan2
- AC073111.3 | c.390C>T p.G130= | Silent (SNP) | VAF 184/812 reads (23%) | catalogued as rs1024605643; called by muse, mutect2
- ACIN1 | c.222G>T p.A74= | Silent (SNP) | VAF 114/850 reads (13%) | catalogued as COSV52977419; called by muse, mutect2
- ADAMTS6 | c.948C>T p.H316= | Silent (SNP) | VAF 29/189 reads (15%) | catalogued as COSV66856382; called by muse, mutect2, varscan2
- ADGRB2 | c.1152C>T p.S384= | Silent (SNP) | VAF 74/958 reads (8%) | catalogued as COSV57079549; called by muse, mutect2
- AGAP1 | c.138C>T p.I46= | Silent (SNP) | VAF 93/454 reads (20%) | catalogued as rs1233050699; called by muse, mutect2
- AL135905.2 | c.57T>C p.L19= | Silent (SNP) | VAF 122/419 reads (29%) | called by muse, mutect2
- AMD1 | c.261G>A p.L87= | Silent (SNP) | VAF 95/280 reads (34%) | catalogued as rs1284561715, COSV64386891; called by muse, mutect2, varscan2
- ANKFN1 | c.768G>T p.R256= | Silent (SNP) | VAF 102/228 reads (45%) | catalogued as rs760059035; called by muse, mutect2, varscan2
- ANKRD52 | c.81A>C p.L27= | Silent (SNP) | VAF 58/455 reads (13%) | catalogued as rs748891036; called by muse, mutect2
- ANKS1B | c.3045A>G p.K1015= | Silent (SNP) | VAF 46/203 reads (23%) | called by muse, varscan2
- ARHGEF9 | c.90A>G p.K30= | Silent (SNP) | VAF 37/242 reads (15%) | called by muse, mutect2, varscan2
- ARID1A | c.90G>A p.Q30= | Silent (SNP) | VAF 138/939 reads (15%) | called by muse, varscan2
- ARL4C | c.555C>T p.S185= | Silent (SNP) | VAF 68/404 reads (17%) | called by muse, mutect2
- ARL4C | c.282C>T p.D94= | Silent (SNP) | VAF 120/566 reads (21%) | catalogued as rs1456019667, COSV60213348; called by muse, mutect2
- ASCL4 | c.243C>T p.R81= | Silent (SNP) | VAF 282/510 reads (55%) | catalogued as rs1217962466; called by muse, mutect2, varscan2
- ASTN1 | c.1368A>G p.G456= | Silent (SNP) | VAF 59/351 reads (17%) | catalogued as COSV56072160; called by muse, varscan2
- BAZ2B | c.3354G>C p.L1118= | Silent (SNP) | VAF 64/400 reads (16%) | catalogued as COSV54274862; called by muse, mutect2
- BCL11A | c.2046G>A p.T682= (on ENST00000335712 / NM_001365609.1; = p.T716= on NM_018014.4) | Silent (SNP) | VAF 148/858 reads (17%) | catalogued as rs535874156, COSV59623888; called by muse, mutect2
- BCL11A | c.501C>T p.S167= (on ENST00000335712 / NM_001365609.1; = p.S201= on NM_018014.4) | Silent (SNP) | VAF 104/681 reads (15%) | catalogued as rs756904803, COSV59623528; called by muse, mutect2, varscan2
- BCL9 | c.312C>G p.S104= | Silent (SNP) | VAF 122/810 reads (15%) | catalogued as rs782011412, COSV52340386; called by muse, varscan2
- BCLAF1 | c.2472T>C p.T824= | Silent (SNP) | VAF 42/249 reads (17%) | called by muse, mutect2
- BEND5 | c.759T>C p.D253= | Silent (SNP) | VAF 36/287 reads (13%) | catalogued as COSV65716367; called by muse, mutect2
- BIRC6 | c.4893A>G p.L1631= | Silent (SNP) | VAF 84/335 reads (25%) | catalogued as COSV70195417, COSV70207251; called by muse, mutect2
- BLK | c.601C>T p.L201= | Silent (SNP) | VAF 112/228 reads (49%) | called by muse, mutect2, varscan2
- BMP4 | c.90G>C p.T30= | Silent (SNP) | VAF 71/485 reads (15%) | catalogued as rs773605577, COSV55415101, COSV55416601; called by muse, mutect2, varscan2
- BRSK1 | c.1794C>T p.N598= | Silent (SNP) | VAF 24/341 reads (7%) | catalogued as rs1425546172; called by muse, mutect2
- C12orf66 | c.99T>C p.A33= | Silent (SNP) | VAF 100/541 reads (18%) | catalogued as COSV61323524; called by muse, mutect2
- CAPZA1 | c.828C>T p.S276= | Silent (SNP) | VAF 95/474 reads (20%) | called by muse, mutect2
- CCNL1 | c.549A>G p.K183= | Silent (SNP) | VAF 30/336 reads (9%) | catalogued as COSV55817116; called by muse, mutect2
- CDH18 | c.1788T>C p.R596= | Silent (SNP) | VAF 82/483 reads (17%) | catalogued as COSV56960322; called by muse, mutect2
- CDH18 | c.1680T>G p.V560= | Silent (SNP) | VAF 83/344 reads (24%) | catalogued as COSV56929558; called by muse, mutect2
- CELF1 | c.705T>A p.L235= (on ENST00000358597 / NM_001376422.1; = p.L231= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 34/390 reads (9%) | called by muse, mutect2
- CEP192 | c.2973G>A p.L991= | Silent (SNP) | VAF 182/182 reads (100%) | called by muse, mutect2, varscan2
- CHD4 | c.4008C>A p.S1336= (on ENST00000357008 / NM_001363606.2; = p.S1349= on NM_001273.5) | Silent (SNP) | VAF 211/1124 reads (19%) | catalogued as COSV58894649; called by muse, varscan2
- CHD4 | c.3870T>A p.I1290= (on ENST00000357008 / NM_001363606.2; = p.I1303= on NM_001273.5) | Silent (SNP) | VAF 116/634 reads (18%) | catalogued as COSV58893929; called by muse, varscan2
- CLASP1 | c.2232T>C p.P744= | Silent (SNP) | VAF 53/431 reads (12%) | called by muse, mutect2
- CLK3 | c.870T>C p.G290= (on ENST00000395066 / NM_001130028.1; = p.G142= on NM_003992.4) | Silent (SNP) | VAF 56/381 reads (15%) | catalogued as rs1323690218, COSV61411668; called by muse, mutect2, varscan2
- CLSTN3 | c.1809G>A p.T603= | Silent (SNP) | VAF 130/904 reads (14%) | catalogued as rs753159999, COSV56934687; called by muse, mutect2
- CNOT1 | c.6366A>T p.P2122= | Silent (SNP) | VAF 70/389 reads (18%) | catalogued as COSV55312762; called by muse, mutect2
- CNOT1 | c.552C>A p.L184= | Silent (SNP) | VAF 58/360 reads (16%) | catalogued as COSV57764213; called by muse, mutect2
- CNOT1 | c.72T>C p.N24= | Silent (SNP) | VAF 36/243 reads (15%) | catalogued as rs760935909; called by muse, mutect2, varscan2
- COL6A3 | c.2304C>T p.R768= | Silent (SNP) | VAF 151/319 reads (47%) | catalogued as rs748301065; called by muse, mutect2, varscan2
- CPAMD8 | c.5439G>A p.S1813= (on ENST00000651564; = p.S1766= on NM_015692.5) | Silent (SNP) | VAF 150/334 reads (45%) | called by muse, mutect2, varscan2
- CREB3L1 | c.1230C>T p.A410= | Silent (SNP) | VAF 127/552 reads (23%) | catalogued as rs573320584; called by muse, mutect2, varscan2
- CSNK1G3 | c.1134C>T p.H378= | Silent (SNP) | VAF 52/314 reads (17%) | catalogued as COSV62053343; called by muse, mutect2
- CTDNEP1 | c.72C>T p.F24= | Silent (SNP) | VAF 70/377 reads (19%) | catalogued as rs780212973; called by muse, mutect2, varscan2
- CTNNA2 | c.382A>C p.R128= | Silent (SNP) | VAF 352/633 reads (56%) | called by muse, mutect2, varscan2
- CXXC4 | c.1053A>G p.S351= | Silent (SNP) | VAF 52/310 reads (17%) | catalogued as rs750196841, COSV67295660; called by muse, mutect2
- CXXC4 | c.696C>G p.R232= | Silent (SNP) | VAF 103/401 reads (26%) | catalogued as COSV67295676; called by muse, varscan2
- CYFIP1 | c.1794G>A p.E598= | Silent (SNP) | VAF 36/484 reads (7%) | called by muse, mutect2
- CYFIP2 | c.915G>A p.V305= | Silent (SNP) | VAF 46/314 reads (15%) | called by muse, mutect2
- DCAF5 | c.147C>T p.L49= | Silent (SNP) | VAF 112/667 reads (17%) | catalogued as rs1254859645, COSV58460945; called by muse, mutect2, varscan2
- DHX15 | c.1827C>T p.A609= | Silent (SNP) | VAF 28/274 reads (10%) | catalogued as rs201398313, COSV61027253; called by muse, mutect2
- DISP2 | c.3606G>A p.P1202= | Silent (SNP) | VAF 356/563 reads (63%) | catalogued as rs142598891; called by muse, mutect2, varscan2
- DLGAP1 | c.2859C>G p.S953= | Silent (SNP) | VAF 150/658 reads (23%) | catalogued as rs1394902811, COSV59810828; called by muse, varscan2
- DLK2 | c.222A>C p.P74= | Silent (SNP) | VAF 68/446 reads (15%) | called by muse, mutect2
- DSCAM | c.2799G>A p.Q933= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as COSV68020046; called by muse, mutect2
- DUSP1 | c.720C>T p.A240= | Silent (SNP) | VAF 30/271 reads (11%) | called by muse, mutect2
- DYNLL2 | c.180A>G p.R60= | Silent (SNP) | VAF 74/421 reads (18%) | catalogued as COSV74093366; called by muse, mutect2
- EBF3 | c.687A>T p.S229= | Silent (SNP) | VAF 70/544 reads (13%) | called by muse, mutect2
- EFNA3 | c.583C>T p.L195= | Silent (SNP) | VAF 46/525 reads (9%) | catalogued as COSV100860807; called by muse, mutect2
- EIF5 | c.303A>G p.E101= | Silent (SNP) | VAF 36/298 reads (12%) | catalogued as rs755543880; called by muse, mutect2
- EPB41L2 | c.2691C>T p.V897= | Silent (SNP) | VAF 50/225 reads (22%) | called by muse, varscan2
- EPHA5 | c.831C>T p.S277= | Silent (SNP) | VAF 129/294 reads (44%) | catalogued as rs377555731, COSV99901104; called by muse, mutect2, varscan2
- ESX1 | c.1011G>A p.A337= | Silent (SNP) | VAF 302/954 reads (32%) | catalogued as rs782565029; called by muse, varscan2
- ESX1 | c.984G>A p.A328= | Silent (SNP) | VAF 238/938 reads (25%) | catalogued as rs1330768144; called by muse, varscan2
- ETV6 | c.1233A>C p.P411= | Silent (SNP) | VAF 70/356 reads (20%) | catalogued as COSV56766063; called by muse, mutect2
- FAM120A | c.42C>T p.C14= | Silent (SNP) | VAF 86/513 reads (17%) | called by muse, mutect2
- FAM13B | c.117A>G p.P39= | Silent (SNP) | VAF 37/245 reads (15%) | catalogued as COSV50364184; called by muse, mutect2
- FAM155B | c.540C>G p.P180= | Silent (SNP) | VAF 254/530 reads (48%) | called by muse, varscan2
- FAM222B | c.891C>T p.P297= | Silent (SNP) | VAF 117/806 reads (15%) | catalogued as COSV57927626; called by muse, mutect2
- FAM53A | c.414C>A p.R138= | Silent (SNP) | VAF 223/482 reads (46%) | called by muse, mutect2, varscan2
- FAR1 | c.1038T>C p.H346= | Silent (SNP) | VAF 58/464 reads (13%) | called by muse, mutect2
- FBXL20 | c.576G>A p.R192= | Silent (SNP) | VAF 61/319 reads (19%) | catalogued as rs1397383183, COSV99233676; called by muse, mutect2
- FBXL20 | c.501A>C p.G167= | Silent (SNP) | VAF 40/227 reads (18%) | called by muse, mutect2
- FBXO32 | c.441T>C p.N147= | Silent (SNP) | VAF 46/542 reads (8%) | called by muse, mutect2
- FLNC | c.7740C>G p.P2580= | Silent (SNP) | VAF 126/516 reads (24%) | catalogued as rs1405401300; called by muse, mutect2, varscan2
- FOXD3 | c.657G>C p.P219= | Silent (SNP) | VAF 86/694 reads (12%) | catalogued as COSV64379719, COSV64380138; called by muse, mutect2
- FOXG1 | c.987C>G p.G329= | Silent (SNP) | VAF 95/731 reads (13%) | catalogued as COSV57395015; called by muse, mutect2
- FOXQ1 | c.603G>A p.E201= | Silent (SNP) | VAF 80/590 reads (14%) | catalogued as rs1427650688; called by muse, mutect2
- FUS | c.777T>C p.R259= | Silent (SNP) | VAF 61/414 reads (15%) | catalogued as COSV54215435; called by muse, mutect2, varscan2
- G3BP2 | c.1110G>A p.K370= | Silent (SNP) | VAF 34/277 reads (12%) | called by muse, mutect2
- GABARAPL1 | c.201A>G p.R67= | Silent (SNP) | VAF 76/616 reads (12%) | called by muse, mutect2
- GALNTL6 | c.807C>T p.F269= | Silent (SNP) | VAF 78/388 reads (20%) | catalogued as rs1331132944, COSV72489234; called by muse, mutect2
- GJC2 | c.639C>T p.Y213= | Silent (SNP) | VAF 557/558 reads (100%) | called by muse, mutect2, varscan2
- GNA13 | c.219G>C p.G73= | Silent (SNP) | VAF 147/714 reads (21%) | catalogued as COSV71474384, COSV71474868; called by muse, mutect2
- GNA14 | c.534C>T p.V178= | Silent (SNP) | VAF 129/296 reads (44%) | called by muse, mutect2, varscan2
- GNG5 | c.156A>G p.V52= | Silent (SNP) | VAF 183/500 reads (37%) | catalogued as COSV55364658; called by muse, mutect2
- GPCPD1 | c.255G>C p.V85= | Silent (SNP) | VAF 66/554 reads (12%) | catalogued as COSV66830366; called by muse, mutect2
- GRIA2 | c.1728G>A p.E576= | Silent (SNP) | VAF 33/191 reads (17%) | catalogued as COSV52380962; called by muse, varscan2
- GRIA3 | c.2631T>C p.Y877= | Silent (SNP) | VAF 16/432 reads (4%) | catalogued as rs1219675668, COSV52048956; called by muse, mutect2
- GRIK2 | c.1758T>C p.P586= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as COSV59711493; called by muse, mutect2
- GRIN2B | c.1923C>T p.I641= | Silent (SNP) | VAF 86/373 reads (23%) | catalogued as COSV74205428; called by muse, mutect2
- HAND2 | c.612G>A p.T204= | Silent (SNP) | VAF 40/416 reads (10%) | catalogued as rs868204890, COSV64019259; called by muse, mutect2
- HERPUD2 | c.33C>T p.T11= | Silent (SNP) | VAF 26/457 reads (6%) | catalogued as COSV60945601; called by muse, mutect2
- HIC1 | c.246C>A p.L82= (on ENST00000322941 / NM_001098202.1; = p.L63= on NM_006497.4) | Silent (SNP) | VAF 82/541 reads (15%) | catalogued as COSV53964464; called by muse, mutect2
- HNRNPAB | c.864T>G p.P288= | Silent (SNP) | VAF 89/466 reads (19%) | catalogued as COSV57422728; called by muse, varscan2
- HNRNPD | c.939T>A p.G313= (on ENST00000313899 / NM_031370.3; = p.G294= on NM_031369.2) | Silent (SNP) | VAF 31/231 reads (13%) | catalogued as COSV58312752, COSV58313794; called by muse, mutect2, varscan2
- HNRNPD | c.441A>G p.E147= | Silent (SNP) | VAF 30/187 reads (16%) | catalogued as COSV58313957; called by muse, varscan2
- HNRNPD | c.324T>C p.T108= | Silent (SNP) | VAF 39/216 reads (18%) | catalogued as COSV58312762; called by muse, mutect2, varscan2
- HNRNPH1 | c.1074A>G p.E358= | Silent (SNP) | VAF 34/266 reads (13%) | catalogued as COSV61484713; called by muse, mutect2, varscan2
- HNRNPR | c.1863G>A p.Q621= | Silent (SNP) | VAF 74/282 reads (26%) | catalogued as COSV56419663; called by muse, mutect2
- HOXA11 | c.279C>T p.C93= | Silent (SNP) | VAF 268/1626 reads (16%) | catalogued as COSV50052771; called by muse, mutect2
- HOXA11 | c.100C>T p.L34= | Silent (SNP) | VAF 184/1068 reads (17%) | catalogued as COSV50052775; called by muse, varscan2
- HOXC11 | c.768T>C p.Y256= | Silent (SNP) | VAF 96/513 reads (19%) | catalogued as COSV54532202; called by muse, mutect2
- HOXD8 | c.561G>C p.P187= | Silent (SNP) | VAF 54/284 reads (19%) | called by muse, varscan2
- HRNR | c.3444C>T p.S1148= | Silent (SNP) | VAF 149/967 reads (15%) | catalogued as rs759603229; called by muse, mutect2, varscan2
- IER5L | c.66A>G p.R22= | Silent (SNP) | VAF 89/629 reads (14%) | catalogued as rs771719630, COSV65262237; called by muse, mutect2
- IKZF1 | c.237G>A p.A79= | Silent (SNP) | VAF 102/891 reads (11%) | catalogued as rs756261862, COSV58780291; called by muse, mutect2
- IL36RN | c.333C>T p.F111= | Silent (SNP) | VAF 306/480 reads (64%) | catalogued as rs199824136, COSV61010530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ING4 | c.591C>A p.T197= (on ENST00000396807 / NM_001127582.2; = p.T196= on NM_016162.4) | Silent (SNP) | VAF 98/807 reads (12%) | called by muse, mutect2
- IRAK3 | c.681G>A p.L227= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as COSV54164346; called by muse, mutect2, varscan2
- KANSL2 | c.1185T>C p.A395= | Silent (SNP) | VAF 175/626 reads (28%) | catalogued as COSV63479288; called by muse, mutect2
- KAT6A | c.5772C>T p.S1924= | Silent (SNP) | VAF 47/456 reads (10%) | catalogued as COSV55907098; called by muse, mutect2
- KAT6B | c.1008A>G p.R336= | Silent (SNP) | VAF 39/484 reads (8%) | catalogued as COSV54741562; called by muse, mutect2
- KCNMA1 | c.678T>C p.L226= | Silent (SNP) | VAF 28/314 reads (9%) | called by muse, mutect2
- KCNMA1 | c.351G>T p.V117= | Silent (SNP) | VAF 68/536 reads (13%) | called by muse, mutect2
- KCNMA1 | c.271C>T p.L91= | Silent (SNP) | VAF 124/804 reads (15%) | catalogued as COSV54226483; called by muse, mutect2
- KCTD8 | c.66G>A p.S22= | Silent (SNP) | VAF 205/430 reads (48%) | catalogued as rs1289372697, COSV63598833; called by muse, mutect2, varscan2
- KDM2A | c.2406G>T p.T802= | Silent (SNP) | VAF 74/741 reads (10%) | catalogued as COSV58188452; called by muse, mutect2
- KDM6A | c.129C>G p.A43= | Silent (SNP) | VAF 80/558 reads (14%) | called by muse, mutect2
- KLHL4 | c.1329T>C p.T443= | Silent (SNP) | VAF 88/230 reads (38%) | called by muse, varscan2
- KLHL4 | c.1515G>A p.V505= | Silent (SNP) | VAF 79/288 reads (27%) | called by muse, varscan2
- KMT2D | c.16063C>T p.L5355= | Silent (SNP) | VAF 43/472 reads (9%) | called by muse, mutect2
- KRAS | c.495A>G p.Q165= | Silent (SNP) | VAF 22/125 reads (18%) | called by muse, mutect2
- LCORL | c.930T>C p.L310= | Silent (SNP) | VAF 40/250 reads (16%) | catalogued as COSV58832142; called by muse, mutect2
- LDB1 | c.1098A>G p.A366= (on ENST00000425280 / NM_001321612.2; = p.A332= on NM_003893.5) | Silent (SNP) | VAF 61/548 reads (11%) | catalogued as COSV63288811; called by muse, mutect2
- LHX2 | c.81C>G p.P27= | Silent (SNP) | VAF 94/514 reads (18%) | called by muse, mutect2
- LIN54 | c.423T>A p.I141= | Silent (SNP) | VAF 44/259 reads (17%) | catalogued as COSV61199872; called by muse, mutect2
- LMX1B | c.255G>A p.A85= | Silent (SNP) | VAF 128/614 reads (21%) | catalogued as rs763085114, COSV62740182; called by muse, mutect2, varscan2
- LRP6 | c.441T>A p.P147= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV99743039; called by muse, mutect2
- LRP6 | c.354G>T p.R118= | Silent (SNP) | VAF 80/248 reads (32%) | catalogued as COSV54381057; called by muse, mutect2
- LRP6 | c.94C>A p.R32= | Silent (SNP) | VAF 94/310 reads (30%) | catalogued as COSV54381119, COSV54384487; called by muse, mutect2
- LRRC41 | c.57G>A p.A19= | Silent (SNP) | VAF 102/900 reads (11%) | called by muse, mutect2
- MAP7D1 | c.768T>A p.V256= | Silent (SNP) | VAF 46/424 reads (11%) | called by muse, mutect2
- MAPK8IP2 | c.1104C>T p.C368= | Silent (SNP) | VAF 259/544 reads (48%) | called by muse, mutect2, varscan2
- MAPKAPK5 | c.288C>T p.A96= | Silent (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2
- MATN4 | c.1335C>T p.T445= (on ENST00000372754; = p.T404= on NM_003833.4) | Silent (SNP) | VAF 429/1104 reads (39%) | catalogued as rs772372562; called by muse, mutect2, varscan2
- MATR3 | c.810A>G p.R270= | Silent (SNP) | VAF 61/250 reads (24%) | catalogued as COSV63075533; called by muse, varscan2
- MBNL1 | c.990A>G p.Q330= (on ENST00000282486 / NM_207293.2; = p.Q312= on NM_021038.5 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 56/274 reads (20%) | catalogued as COSV56824898; called by muse, varscan2
- MED1 | c.1956T>C p.N652= | Silent (SNP) | VAF 76/417 reads (18%) | catalogued as COSV56122107; called by muse, mutect2
- MED13 | c.3672A>G p.E1224= | Silent (SNP) | VAF 109/244 reads (45%) | called by muse, mutect2, varscan2
- MED25 | c.2028T>G p.P676= | Silent (SNP) | VAF 103/508 reads (20%) | called by muse, mutect2, varscan2
- MEIS1 | c.366C>G p.A122= | Silent (SNP) | VAF 62/365 reads (17%) | catalogued as COSV99715877; called by muse, mutect2, varscan2
- MEIS2 | c.1074A>G p.A358= (on ENST00000561208 / NM_170675.5; = p.A338= on NM_002399.3) | Silent (SNP) | VAF 42/364 reads (12%) | catalogued as COSV54937806; called by muse, varscan2
- MEMO1 | c.444G>A p.K148= | Silent (SNP) | VAF 34/194 reads (18%) | called by muse, mutect2, varscan2
- MEX3A | c.126C>T p.L42= | Silent (SNP) | VAF 100/593 reads (17%) | catalogued as rs759361158, COSV64141064; called by muse, varscan2
- MEX3C | c.6C>A p.P2= | Silent (SNP) | VAF 52/146 reads (36%) | called by muse, mutect2
- MGAT5 | c.531A>C p.G177= | Silent (SNP) | VAF 84/190 reads (44%) | called by muse, mutect2, varscan2
- MICU3 | c.195G>A p.G65= | Silent (SNP) | VAF 300/651 reads (46%) | catalogued as COSV100536637; called by mutect2, varscan2
- MLLT10 | c.60G>A p.E20= | Silent (SNP) | VAF 58/460 reads (13%) | catalogued as rs999558563, COSV56990751; called by muse, varscan2
- MLLT3 | c.627A>G p.K209= | Silent (SNP) | VAF 78/362 reads (22%) | catalogued as COSV63494445; called by muse, mutect2
- MLLT6 | c.57G>A p.E19= | Silent (SNP) | VAF 118/608 reads (19%) | catalogued as rs1200137336; called by muse, varscan2
- MTA1 | c.1245T>C p.R415= | Silent (SNP) | VAF 51/668 reads (8%) | catalogued as COSV58755542; called by muse, mutect2
- MTF2 | c.561A>T p.A187= | Silent (SNP) | VAF 52/434 reads (12%) | called by muse, mutect2
- MTSS1 | c.1164A>T p.P388= | Silent (SNP) | VAF 92/1224 reads (8%) | called by muse, mutect2
- MYH11 | c.1458C>G p.L486= | Silent (SNP) | VAF 78/652 reads (12%) | called by muse, mutect2
- MYH9 | c.3018C>T p.T1006= | Silent (SNP) | VAF 99/207 reads (48%) | catalogued as rs531017680, COSV53390889; called by muse, mutect2, varscan2
- NBEAL1 | c.1689A>C p.L563= | Silent (SNP) | VAF 136/495 reads (27%) | called by muse, mutect2, varscan2
- NCKAP1 | c.87C>G p.T29= | Silent (SNP) | VAF 73/823 reads (9%) | catalogued as rs770856966; called by muse, mutect2
- NCOA1 | c.4164A>G p.Q1388= | Silent (SNP) | VAF 70/321 reads (22%) | catalogued as rs1466346856, COSV56038443; called by muse, mutect2
- NCOR1 | c.5764A>C p.R1922= | Silent (SNP) | VAF 74/418 reads (18%) | catalogued as COSV51959292, COSV51965623; called by muse, mutect2
- NEUROD6 | c.978A>T p.T326= | Silent (SNP) | VAF 78/544 reads (14%) | catalogued as COSV51769376; called by muse, varscan2
- NKAIN4 | c.42C>T p.C14= | Silent (SNP) | VAF 347/941 reads (37%) | catalogued as rs1316115744; called by muse, mutect2, varscan2
- NPEPPS | c.810T>C p.T270= | Silent (SNP) | VAF 48/294 reads (16%) | catalogued as rs1210111634; called by muse, mutect2
- NPEPPS | c.1887A>C p.G629= | Silent (SNP) | VAF 50/202 reads (25%) | catalogued as COSV59100586; called by muse, mutect2
- NPTN | c.393C>T p.P131= | Silent (SNP) | VAF 65/431 reads (15%) | catalogued as rs577243481, COSV54736552; called by muse, mutect2, varscan2
- NPTN | c.171C>T p.S57= | Silent (SNP) | VAF 58/400 reads (15%) | catalogued as rs1052757996, COSV54736565; called by muse, mutect2, varscan2
- NR4A2 | c.1428T>G p.V476= | Silent (SNP) | VAF 78/400 reads (20%) | catalogued as COSV59892558; called by muse, varscan2
- NR4A2 | c.153C>T p.I51= | Silent (SNP) | VAF 86/426 reads (20%) | catalogued as COSV59892427; called by muse, mutect2, varscan2
- NRCAM | c.645C>T p.D215= (on ENST00000379028 / NM_001371124.1; = p.D209= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 74/427 reads (17%) | called by muse, mutect2, varscan2
- NRG1 | c.1275G>A p.V425= (on ENST00000405005 / NM_013964.5; = p.V430= on NM_013956.5) | Silent (SNP) | VAF 39/259 reads (15%) | called by muse, mutect2
- NRXN2 | c.1080T>C p.L360= | Silent (SNP) | VAF 48/622 reads (8%) | catalogued as COSV55455306; called by muse, mutect2
- NWD2 | c.4998C>T p.F1666= | Silent (SNP) | VAF 126/379 reads (33%) | called by muse, mutect2, varscan2
- OAZ2 | c.276T>C p.S92= | Silent (SNP) | VAF 88/572 reads (15%) | catalogued as rs1405315382, COSV58106134; called by muse, mutect2
- PABPC1 | c.168T>C p.Y56= | Silent (SNP) | VAF 56/544 reads (10%) | catalogued as rs1177233161; called by muse, mutect2, varscan2
- PARP6 | c.429A>G p.K143= | Silent (SNP) | VAF 32/374 reads (9%) | called by muse, mutect2
- PATZ1 | c.1590G>A p.E530= | Silent (SNP) | VAF 88/463 reads (19%) | catalogued as COSV56743083; called by muse, mutect2, varscan2
- PAX2 | c.186C>T p.H62= | Silent (SNP) | VAF 77/727 reads (11%) | catalogued as rs765130310, COSV62291371; called by muse, mutect2, varscan2
- PAXBP1 | c.307C>A p.R103= | Silent (SNP) | VAF 52/530 reads (10%) | called by muse, mutect2
- PAXBP1 | c.261C>T p.N87= | Silent (SNP) | VAF 60/722 reads (8%) | catalogued as rs1026398125, COSV99268954; called by muse, mutect2
- PBX4 | c.432A>G p.K144= | Silent (SNP) | VAF 28/230 reads (12%) | called by muse, mutect2
- PCDH17 | c.2928T>C p.P976= | Silent (SNP) | VAF 72/351 reads (21%) | catalogued as rs1472469777, COSV64971372; called by muse, mutect2
- PCSK5 | c.1233A>G p.V411= | Silent (SNP) | VAF 48/304 reads (16%) | catalogued as COSV65082798; called by muse, mutect2
- PDE4D | c.882A>G p.L294= (on ENST00000340635 / NM_001104631.2; = p.L158= on NM_006203.4) | Silent (SNP) | VAF 42/339 reads (12%) | catalogued as rs1450116495; called by muse, mutect2
- PDZD2 | c.1092T>C p.T364= | Silent (SNP) | VAF 62/326 reads (19%) | called by muse, mutect2
- PIP4K2B | c.126C>T p.I42= | Silent (SNP) | VAF 123/682 reads (18%) | catalogued as rs1303764071; called by muse, mutect2
- PIP4K2B | c.60G>A p.K20= | Silent (SNP) | VAF 207/873 reads (24%) | catalogued as rs954920516; called by muse, mutect2
- PKP4 | c.225A>G p.S75= | Silent (SNP) | VAF 45/273 reads (16%) | called by muse, mutect2
- PLEKHA6 | c.2988C>T p.C996= | Silent (SNP) | VAF 80/492 reads (16%) | catalogued as rs112731457, COSV55342151; called by muse, mutect2
- PODXL2 | c.1653C>T p.N551= | Silent (SNP) | VAF 110/872 reads (13%) | called by muse, mutect2
- POU3F1 | c.885C>T p.R295= | Silent (SNP) | VAF 51/578 reads (9%) | catalogued as rs1323985493, COSV65948430; called by muse, mutect2
- POU3F2 | c.1131C>T p.P377= | Silent (SNP) | VAF 62/514 reads (12%) | catalogued as COSV60408470, COSV60409482; called by muse, mutect2
- POU6F2 | c.147T>C p.P49= | Silent (SNP) | VAF 46/723 reads (6%) | catalogued as COSV68867342, COSV68873301; called by muse, mutect2
- PPARGC1A | c.1770T>C p.S590= | Silent (SNP) | VAF 30/304 reads (10%) | called by muse, mutect2
- PPIP5K2 | c.3033T>C p.T1011= | Silent (SNP) | VAF 68/346 reads (20%) | catalogued as COSV58602547; called by muse, mutect2
- PPP2CA | c.69G>C p.L23= | Silent (SNP) | VAF 76/384 reads (20%) | called by muse, mutect2
- PPP2R5E | c.319T>C p.L107= | Silent (SNP) | VAF 26/226 reads (12%) | called by muse, mutect2
- PPP4R3A | c.1146T>G p.T382= | Silent (SNP) | VAF 30/465 reads (6%) | called by muse, mutect2
- PRICKLE1 | c.1203T>G p.T401= | Silent (SNP) | VAF 219/336 reads (65%) | called by muse, mutect2, varscan2
- PROX1 | c.54A>G p.R18= | Silent (SNP) | VAF 60/328 reads (18%) | catalogued as COSV54775452; called by muse, mutect2
- PRR7 | c.36G>T p.T12= | Silent (SNP) | VAF 44/425 reads (10%) | called by muse, mutect2
- PRRC2A | c.174T>C p.P58= | Silent (SNP) | VAF 90/768 reads (12%) | called by muse, mutect2
- PRRC2A | c.240A>G p.P80= | Silent (SNP) | VAF 85/649 reads (13%) | catalogued as rs1266794147; called by muse, mutect2
- PRRX1 | c.651C>T p.G217= | Silent (SNP) | VAF 70/556 reads (13%) | called by muse, mutect2, varscan2
- PSMD14 | c.357T>C p.G119= | Silent (SNP) | VAF 81/332 reads (24%) | catalogued as rs1423428612; called by muse, mutect2
- PTCHD1 | c.2538G>T p.L846= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV65058954; called by muse, mutect2
- PTPRF | c.5179C>T p.L1727= | Silent (SNP) | VAF 52/476 reads (11%) | called by muse, mutect2
- PWWP2A | c.1635A>G p.R545= | Silent (SNP) | VAF 44/280 reads (16%) | called by muse, mutect2
- QKI | c.51C>T p.Y17= | Silent (SNP) | VAF 42/369 reads (11%) | catalogued as rs200474822, COSV51689032; called by muse, mutect2, varscan2
- QKI | c.52C>T p.L18= | Silent (SNP) | VAF 42/372 reads (11%) | catalogued as rs764442951, COSV51689055; called by muse, mutect2, varscan2
- RAB11A | c.382C>T p.L128= | Silent (SNP) | VAF 33/310 reads (11%) | catalogued as rs1378332058, COSV56041514; called by muse, mutect2, varscan2
- RAB39B | c.243C>T p.N81= | Silent (SNP) | VAF 28/535 reads (5%) | catalogued as COSV65624323; called by muse, mutect2
- RADX | c.1239A>G p.E413= | Silent (SNP) | VAF 65/285 reads (23%) | called by muse, mutect2, varscan2
- RAP2A | c.87C>T p.I29= | Silent (SNP) | VAF 62/486 reads (13%) | catalogued as COSV55354229; called by muse, mutect2
- RARA | c.738G>T p.L246= | Silent (SNP) | VAF 136/654 reads (21%) | catalogued as COSV54189522; called by muse, mutect2
- RBM14 | c.1974G>A p.A658= | Silent (SNP) | VAF 58/429 reads (14%) | catalogued as rs777677688, COSV59557733; called by muse, mutect2, varscan2
- RBM25 | c.894G>A p.K298= | Silent (SNP) | VAF 32/350 reads (9%) | catalogued as COSV56202075; called by muse, mutect2
- RBM27 | c.906C>T p.P302= | Silent (SNP) | VAF 35/273 reads (13%) | called by muse, mutect2, varscan2
- RNF130 | c.1191C>T p.A397= | Silent (SNP) | VAF 66/358 reads (18%) | catalogued as COSV56149564, COSV56151035; called by muse, mutect2
- ROR2 | c.1545G>T p.G515= | Silent (SNP) | VAF 76/373 reads (20%) | catalogued as COSV65217893; called by muse, mutect2, varscan2
- SAMD1 | c.213C>G p.A71= | Silent (SNP) | VAF 143/643 reads (22%) | catalogued as COSV54115564; called by muse, mutect2, varscan2
- SAMD1 | c.105C>T p.I35= | Silent (SNP) | VAF 92/453 reads (20%) | catalogued as rs1426383241, COSV54115669; called by muse, varscan2
- SAMD4A | c.843C>T p.P281= | Silent (SNP) | VAF 71/446 reads (16%) | catalogued as COSV51876289; called by muse, varscan2
- SAMD4A | c.972G>T p.G324= | Silent (SNP) | VAF 24/166 reads (14%) | called by muse, varscan2
- SESTD1 | c.1185T>C p.D395= | Silent (SNP) | VAF 53/265 reads (20%) | called by muse, mutect2
- SETD1B | c.132T>C p.H44= | Silent (SNP) | VAF 105/512 reads (21%) | catalogued as COSV57354311; called by muse, mutect2, varscan2
- SETD5 | c.450T>C p.Y150= | Silent (SNP) | VAF 109/433 reads (25%) | catalogued as COSV56712199; called by muse, mutect2, varscan2
- SF1 | c.168G>A p.L56= | Silent (SNP) | VAF 61/406 reads (15%) | catalogued as COSV57110890; called by muse, varscan2
- SFMBT2 | c.282C>T p.A94= | Silent (SNP) | VAF 104/245 reads (42%) | called by muse, mutect2, varscan2
- SGMS1 | c.717T>C p.G239= | Silent (SNP) | VAF 30/257 reads (12%) | catalogued as rs1272603950; called by muse, mutect2
- SHISA2 | c.214T>C p.L72= | Silent (SNP) | VAF 92/744 reads (12%) | called by muse, mutect2
- SHISA2 | c.162T>C p.C54= | Silent (SNP) | VAF 97/781 reads (12%) | catalogued as rs1232928258, COSV100096376; called by muse, mutect2
- SHOX2 | c.768T>C p.A256= (on ENST00000441443 / NM_006884.3; = p.A280= on NM_003030.4) | Silent (SNP) | VAF 104/996 reads (10%) | catalogued as COSV67464030; called by muse, mutect2
- SIGLEC1 | c.3630C>A p.R1210= | Silent (SNP) | VAF 268/1149 reads (23%) | called by muse, mutect2, varscan2
- SIX3 | c.244C>T p.L82= | Silent (SNP) | VAF 89/485 reads (18%) | catalogued as rs765191003, COSV53226318; called by muse, mutect2
- SLC22A4 | c.69C>T p.F23= | Silent (SNP) | VAF 88/556 reads (16%) | called by muse, varscan2
- SLC35E3 | c.273T>C p.T91= | Silent (SNP) | VAF 209/711 reads (29%) | catalogued as COSV57492711; called by muse, mutect2
- SMARCC2 | c.87G>C p.L29= | Silent (SNP) | VAF 76/507 reads (15%) | catalogued as rs749666044; called by muse, mutect2, varscan2
- SMARCD3 | c.105G>A p.R35= (on ENST00000262188 / NM_001003801.2; = p.R22= on NM_003078.4) | Silent (SNP) | VAF 81/442 reads (18%) | called by muse, mutect2
- SMG6 | c.3456G>A p.K1152= | Silent (SNP) | VAF 87/524 reads (17%) | catalogued as rs970711004, COSV53962905; called by muse, mutect2
- SNTB2 | c.450T>G p.A150= | Silent (SNP) | VAF 222/862 reads (26%) | catalogued as rs1197353929, COSV60352376; called by muse, mutect2
- SOGA3 | c.537C>T p.G179= | Silent (SNP) | VAF 410/417 reads (98%) | called by muse, mutect2, varscan2
- SOX11 | c.1254G>A p.T418= | Silent (SNP) | VAF 166/386 reads (43%) | catalogued as COSV58987659; called by muse, varscan2
- SREK1 | c.288G>T p.V96= | Silent (SNP) | VAF 37/339 reads (11%) | called by muse, mutect2
- SRSF10 | c.627T>G p.S209= | Silent (SNP) | VAF 54/388 reads (14%) | called by muse, mutect2, varscan2
- STRBP | c.732A>G p.E244= | Silent (SNP) | VAF 33/181 reads (18%) | catalogued as rs1283035909; called by muse, mutect2, varscan2
- SYN2 | c.1638C>G p.A546= | Silent (SNP) | VAF 98/392 reads (25%) | catalogued as COSV70285655; called by muse, mutect2
- SYN2 | c.1683G>A p.E561= | Silent (SNP) | VAF 146/493 reads (30%) | called by muse, mutect2
- SYNCRIP | c.57T>A p.S19= | Silent (SNP) | VAF 44/238 reads (18%) | catalogued as COSV62286559; called by muse, varscan2
- SYNRG | c.2604T>C p.A868= | Silent (SNP) | VAF 46/276 reads (17%) | catalogued as rs773967025; called by muse, mutect2
- SYT1 | c.1116T>C p.D372= | Silent (SNP) | VAF 42/338 reads (12%) | called by muse, mutect2
- TACC2 | c.8640C>T p.H2880= (on ENST00000334433; = p.H958= on NM_006997.4) | Silent (SNP) | VAF 91/217 reads (42%) | catalogued as rs554081729, COSV53277336; called by muse, mutect2, varscan2
- TACO1 | c.813C>T p.P271= | Silent (SNP) | VAF 157/297 reads (53%) | catalogued as rs151139810; called by muse, mutect2, varscan2
- TENM1 | c.2970T>G p.P990= | Silent (SNP) | VAF 176/474 reads (37%) | called by muse, mutect2, varscan2
- TENM2 | c.624A>G p.Q208= | Silent (SNP) | VAF 106/436 reads (24%) | catalogued as COSV69123892; called by muse, mutect2
- TENM2 | c.2292G>T p.A764= (on ENST00000518659 / NM_001122679.2; = p.A532= on NM_001080428.3) | Silent (SNP) | VAF 88/424 reads (21%) | catalogued as COSV69122442; called by muse, mutect2, varscan2
- TGIF1 | c.222C>T p.L74= (on ENST00000330513 / NM_001374396.1; = p.L94= on NM_003244.4) | Silent (SNP) | VAF 73/396 reads (18%) | called by muse, mutect2
- TMEM63B | c.1875C>T p.A625= | Silent (SNP) | VAF 86/514 reads (17%) | catalogued as rs1194072112, COSV52479973; called by muse, mutect2
- TNR | c.1101C>T p.L367= | Silent (SNP) | VAF 90/633 reads (14%) | catalogued as COSV54869502; called by muse, mutect2, varscan2
- TNRC6A | c.5106A>G p.T1702= | Silent (SNP) | VAF 56/332 reads (17%) | catalogued as rs150402538; called by muse, mutect2
- TNRC6B | c.1170G>A p.E390= | Silent (SNP) | VAF 80/388 reads (21%) | catalogued as rs764036673, COSV57287675; called by muse, mutect2, varscan2
- TRIP12 | c.5115C>T p.A1705= | Silent (SNP) | VAF 48/320 reads (15%) | called by muse, mutect2
- TRIP12 | c.2364G>A p.E788= | Silent (SNP) | VAF 43/420 reads (10%) | called by muse, mutect2
- TRPS1 | c.3819G>A p.V1273= (on ENST00000220888 / NM_001330599.2; = p.V1286= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/596 reads (9%) | catalogued as COSV55224506; called by muse, mutect2
- TSPAN2 | c.240C>T p.A80= | Silent (SNP) | VAF 212/338 reads (63%) | called by muse, mutect2, varscan2
- TTBK2 | c.2421A>G p.G807= | Silent (SNP) | VAF 92/251 reads (37%) | called by muse, mutect2, varscan2
- TTPA | c.216C>T p.N72= | Silent (SNP) | VAF 89/182 reads (49%) | called by muse, mutect2, varscan2
- UBR4 | c.8529G>C p.L2843= | Silent (SNP) | VAF 54/386 reads (14%) | called by muse, varscan2
- UBXN7 | c.141T>A p.T47= | Silent (SNP) | VAF 109/399 reads (27%) | called by muse, mutect2, varscan2
- UNC79 | c.222T>C p.P74= | Silent (SNP) | VAF 28/504 reads (6%) | catalogued as COSV56392272; called by muse, mutect2
- USP21 | c.1143T>C p.C381= | Silent (SNP) | VAF 76/580 reads (13%) | called by muse, mutect2
- USP34 | c.8424C>G p.V2808= | Silent (SNP) | VAF 61/373 reads (16%) | catalogued as COSV68397821; called by muse, mutect2, varscan2
- USP34 | c.8094T>C p.R2698= | Silent (SNP) | VAF 50/319 reads (16%) | catalogued as COSV68397829; called by muse, varscan2
- USP7 | c.378T>C p.D126= | Silent (SNP) | VAF 26/189 reads (14%) | called by muse, varscan2
- USP7 | c.225G>C p.V75= | Silent (SNP) | VAF 55/391 reads (14%) | catalogued as COSV61212825; called by muse, mutect2, varscan2
- VGLL1 | c.411G>A p.A137= | Silent (SNP) | VAF 404/655 reads (62%) | catalogued as rs772131546; called by muse, mutect2, varscan2
- WNT9A | c.18G>T p.P6= | Silent (SNP) | VAF 72/393 reads (18%) | called by muse, mutect2
- YTHDF3 | c.972A>G p.Q324= | Silent (SNP) | VAF 68/492 reads (14%) | catalogued as rs1171980454, COSV72773175; called by muse, mutect2
- ZBTB18 | c.603A>C p.A201= | Silent (SNP) | VAF 106/568 reads (19%) | catalogued as COSV62396182; called by muse, mutect2
- ZBTB18 | c.834T>G p.A278= | Silent (SNP) | VAF 109/489 reads (22%) | catalogued as COSV62396192; called by muse, mutect2
- ZC3H14 | c.150T>C p.D50= | Silent (SNP) | VAF 24/348 reads (7%) | called by muse, mutect2
- ZFAND5 | c.297G>A p.Q99= | Silent (SNP) | VAF 46/284 reads (16%) | called by muse, mutect2
- ZFHX4 | c.18C>T p.S6= | Silent (SNP) | VAF 19/321 reads (6%) | catalogued as COSV99266884; called by muse, mutect2
- ZFPM2 | c.1704G>A p.K568= | Silent (SNP) | VAF 104/632 reads (16%) | catalogued as rs774519852; called by muse, mutect2, varscan2
- ZFR | c.168T>C p.S56= | Silent (SNP) | VAF 57/314 reads (18%) | called by muse, mutect2
- ZNF148 | c.2355T>A p.P785= | Silent (SNP) | VAF 60/336 reads (18%) | called by muse, mutect2
- ZNF185 | c.741G>A p.A247= | Silent (SNP) | VAF 118/472 reads (25%) | catalogued as rs1556870318; called by muse, mutect2, varscan2
- ZNF513 | c.522A>G p.G174= | Silent (SNP) | VAF 102/607 reads (17%) | catalogued as COSV52006345; called by muse, mutect2
- ZNF517 | c.915C>T p.N305= | Silent (SNP) | VAF 754/1053 reads (72%) | catalogued as rs770165380; called by muse, mutect2, varscan2
- ZNF831 | c.3177G>A p.T1059= | Silent (SNP) | VAF 219/1131 reads (19%) | catalogued as rs766958870, COSV100926183; called by muse, mutect2, varscan2
- ABI2 | c.1193-5601C>T | Intron (SNP) | VAF 35/388 reads (9%) | catalogued as rs1290659890, COSV53693326; called by muse, mutect2
- ARHGEF1 | c.1122-397C>T | Intron (SNP) | VAF 64/648 reads (10%) | called by muse, mutect2
- ATP2B1 | c.3351+430G>A | Intron (SNP) | VAF 62/310 reads (20%) | catalogued as COSV53803510; called by muse, varscan2
- BRD8 | c.643-508G>A | Intron (SNP) | VAF 69/378 reads (18%) | catalogued as COSV50145126; called by muse, varscan2
- CORO6 | c.634-522C>A | Intron (SNP) | VAF 358/617 reads (58%) | called by muse, mutect2, varscan2
- CSF3R | c.2041-68G>A | Intron (SNP) | VAF 112/305 reads (37%) | called by muse, mutect2, varscan2
- DBN1 | c.956-405C>T | Intron (SNP) | VAF 71/472 reads (15%) | catalogued as rs1396041323; called by muse, varscan2
- EGR3 | c.154+478G>A | Intron (SNP) | VAF 50/524 reads (10%) | called by muse, mutect2
- ELAVL2 | c.-12-2793T>C | Intron (SNP) | VAF 72/404 reads (18%) | called by muse, mutect2
- FBRS | c.-133G>A | 5'UTR (SNP) | VAF 144/835 reads (17%) | catalogued as COSV54916732; called by muse, mutect2
- FRMPD2 | chr10:48156176 A>C | 3'Flank (SNP) | VAF 65/217 reads (30%) | called by muse, mutect2, varscan2
- ILF3 | c.2059+487T>G | Intron (SNP) | VAF 30/216 reads (14%) | catalogued as COSV51554017; called by muse, varscan2
- KCNC1 | chr11:17779556 G>C | 3'Flank (SNP) | VAF 81/750 reads (11%) | catalogued as COSV56397372; called by muse, varscan2
- KIF3A | c.1228+2050C>T | Intron (SNP) | VAF 68/136 reads (50%) | called by muse, mutect2, varscan2
- LUC7L3 | c.*33+84A>G | Intron (SNP) | VAF 61/306 reads (20%) | catalogued as COSV53585599; called by muse, mutect2, varscan2
- MEGF11 | c.2711-2912C>T | Intron (SNP) | VAF 43/412 reads (10%) | catalogued as rs1235240511; called by muse, mutect2, varscan2
- MEGF11 | c.2711-2913C>A | Intron (SNP) | VAF 43/417 reads (10%) | called by muse, mutect2, varscan2
- NFIB | c.1245+4100G>A | Intron (SNP) | VAF 68/298 reads (23%) | catalogued as rs778689333; called by muse, mutect2
- PDE2A | c.72-38C>T | Intron (SNP) | VAF 52/578 reads (9%) | catalogued as rs778291409; called by muse, mutect2
- PDPN | chr1:13583817 G>A | 5'Flank (SNP) | VAF 114/302 reads (38%) | called by muse, mutect2, varscan2
- PHKB | c.2427+999G>A | Intron (SNP) | VAF 38/253 reads (15%) | catalogued as rs1219252481; called by muse, mutect2
- PPP2R2B | c.-59A>T | 5'UTR (SNP) | VAF 75/413 reads (18%) | catalogued as COSV60768468; called by muse, mutect2, varscan2
- RALGAPA1 | c.2267-10250A>T | Intron (SNP) | VAF 40/358 reads (11%) | catalogued as COSV51876292; called by muse, varscan2
- SH3KBP1 | c.521-3626T>C | Intron (SNP) | VAF 29/169 reads (17%) | called by muse, mutect2
- SPDYE16 | chr7:76541449 G>A | 5'Flank (SNP) | VAF 217/546 reads (40%) | catalogued as rs1431340322; called by muse, mutect2, varscan2
- SRSF5 | c.366+263G>A | Intron (SNP) | VAF 61/317 reads (19%) | called by muse, varscan2
- SYN1 | c.*1T>C | 3'UTR (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2
- THRA | c.1110+96C>G | Intron (SNP) | VAF 71/280 reads (25%) | catalogued as COSV52840278; called by muse, mutect2, varscan2
- ZFHX3 | c.-231_-205delinsAGCAGCGCG | 5'UTR (DEL) | VAF 34/362 reads (9%) | called by pindel, varscan2*
